Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-A4CH, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-A4CH-01A (Primary Tumor).

[page 1 of 7]
Department of Pathology

Patient Name: [REDACTED]	Service: Otolaryngology	Copath #: [REDACTED]
MRN: [REDACTED]	Visit #: [REDACTED]	Collected: [REDACTED]
DOB: [REDACTED]	Location:	Resulted: [REDACTED]
Gender: [REDACTED]	Facility:	
Ordering MD: [REDACTED]		

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Soft-Tissue: right neck level 1
2. Neck: Right neck level 2
3. Neck: Right neck level 3 + 4
4. Oral Cavity: near total glossectomy -
5. Oral Cavity: left tongue base -
6. Neck: Left neck level 1A + 1B
7. Neck: Left neck level 2A + 2B
8. Neck: Left neck level 3
9. Neck: Left neck level 4
10. Lymph node: Right perifacial node
11. Surgical Waste

ICD-0-3

Carcinoma, Squamous cell, NOS
8070/3

Situ: tongue, border CO2-1

h
9/24/12

DIAGNOSIS

1. Right neck; level I:
- Submandibular gland with no pathologic changes.
- Two lymph nodes, negative for malignancy (0/2).
2. Right neck; level II:
- Fibroadipose tissue, negative for malignancy. No lymph nodes identified.
3. Right neck; levels III-IV:
- Twenty-three lymph nodes, negative for malignancy (0/23).
4. Near total glossectomy:
- Squamous cell carcinoma, moderately differentiated.
- a. Maximum tumour dimension: 3.6 cm.
- b. Maximum tumour thickness: 1.9 cm.
- c. Perineural invasion is present.
- d. No lymphovascular invasion identified.
- e. Tumour is present at the left lateral margin and is very close (< 0.1 cm) to the posterior margin.

[page 2 of 7]
5. Left tongue base:

Status: complete

Page: 1 of 6

Patient Name [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED]
Gender: [REDACTED]
HCN: [REDACTED]
Ordering MD: [REDACTED]

Service: Otolaryngology
Visit #: [REDACTED]
Location:
Facility:

Copath #: [REDACTED]
Collected: [REDACTED]
Resulted: [REDACTED]

- Negative for malignancy.

6. Left neck; level IA-B:

- Submandibular gland with no pathologic changes.
- Eight lymph nodes, negative for malignancy (0/8).

7. Left neck; level IIA-B:

- Two lymph nodes, negative for malignancy (0/2).

8. Left neck; level III:

- Twelve lymph nodes, negative for malignancy (0/12).

9. Left neck; level IV:

- Seven lymph nodes, negative for malignancy (0/7).

10. Right perifacial lymph node:

- One lymph node and focal parotid tissue, negative for malignancy (0/1).

11. Surgical waste:

- Skin with no gross pathologic changes (see comment).

COMMENT

11. THIS SPECIMEN HAS BEEN EXAMINED BY GROSS VISUAL EXAMINATION ONLY. NO MICROSCOPIC EXAMINATION HAS BEEN PERFORMED. IF THERE IS A CLINICAL INDICATION OR SUSPICION OF AN ABNORMALITY THAT WOULD REQUIRE ADDITIONAL STUDIES THEN THE SIGNING PATHOLOGIST (BELOW) SHOULD BE CONTACTED WITHIN ONE MONTH OF THE ISSUING OF THIS REPORT.

SYNOPTIC DATA

Specimen:
Received:
Procedure:

Other: Near total glossectomy.
Fresh
Glossectomy: Near total.

[page 3 of 7]
Bilateral levels I-IV.
Specimen Size:

Specimen Laterality:
Tumor Site:

Neck (lymph node) dissection:

Greatest dimension: 5.7 cm
Additional dimension: 5.3 cm
Additional dimension: 2.9 cm
Midline
Lateral border of tongue

Status: complete

Page: 2 of 6

Patient Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED]
Gender: [REDACTED]
HCN: [REDACTED]
Ordering MD: [REDACTED]

Service: Otolaryngology
Visit #: [REDACTED]
Location:
Facility:

Copath #: [REDACTED]
Collected: [REDACTED]
Resulted: [REDACTED]

Tumor Focality:
Tumor Size:

Histologic Type:

Histologic Grade:
Margins:
carcinoma

is not applicable

Lymph-Vascular Invasion:
Perineural Invasion:
Lymph Nodes, Extranodal Extension:
TNM Descriptors:
Primary Tumor (pT):
more than 4 cm in greatest dimension
Regional Lymph Nodes (pN):
metastasis

examined: 55

involved: 0

Distant Metastasis (pM):

Single focus
Greatest dimension: 3.6 cm
Additional dimension: 3.1 cm
Additional dimension: 1.9 cm
Squamous cell carcinoma, conventional

G2: Moderately differentiated
Margins involved by invasive

Margin(s): Left lateral margin.
Margin status for carcinoma in situ

Not identified
Present
Not identified
Not applicable
pT2: Tumor more than 2 cm but not

pN0: No regional lymph node

Number of regional lymph nodes

Number of regional lymph nodes

Not applicable

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

[page 4 of 7]
ELECTRONICALLY VERIFIED BY:

GROSS DESCRIPTION

1. The specimen container labeled with the patient's identification and as "soft tissue, right neck level 1" contains a piece of fibroadipose tissue, measuring 5.5 x 3.9 x 1.7 cm. The submandibular gland is identified, measuring 3.3 x 2.0 x 1.7 cm. Two possible lymph nodes are identified, measuring 1.0 x 0.7 x 0.3 cm, and 1.1 x 0.5 x 0.3 cm.

Status: complete

Page: 3 of 6

Patient Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED]
Gender: [REDACTED]
HCN: [REDACTED]
Ordering MD: [REDACTED]

Service: Otolaryngology
Visit #: [REDACTED]
Location:
Facility:

Copath #: [REDACTED]
Collected: [REDACTED]
Resulted: [REDACTED]

Representative sections:

1A Submandibular gland
1B Two possible lymph nodes

2. The specimen container labeled with the patient's identification and as "right neck level 2" contains a single piece of skeletal muscle and attached fibroadipose tissue, measuring 3.1 x 2.7 x 1.7 cm. No lymph nodes are grossly identified.
Representative section in 2A

3. The specimen container labeled with the patient's identification and as "right neck level 3 and 4" contains a single piece of fibroadipose tissue, measuring 4.1 x 2.9 x 1.5 cm. 20 nodular areas are identified, ranging in size from 0.2 x 0.2 x 0.2 cm to 2.1 x 0.9 x 0.5 cm.

Representative sections:

3A-3B 5 nodular areas each cassette
3C-D 4 nodular areas each cassette
3E-G One nodular area, bisected in each cassette

4. The specimen container is labeled with the patient's identification

[page 5 of 7]
and as "near-total glossectomy". It contains a glossectomy specimen, measuring 5.3 cm SI x 5.7 cm ML x 2.9 cm AP. On the anterior left portion of the tongue, there is an exophytic tumor measuring 1.9 cm ML x 3.1 cm AP x 3.6 cm SI. The tumor extends to within 0.2 cm of the left margin, 1.3 cm of the right margin, 4.5 cm of the posterior margin, and 1.2 cm of the deep soft tissue margin. The right aspect of the specimen has been painted with black ink and the left aspect painted with green ink. Sections from the posterior margin were previously submitted at the time of frozen section.

Representative sections

4 A-B frozen section, resubmitted (posterior margin)
4C posterior tongue and posterior soft tissue margin
4D-4E tumor with left lateral margin
4F tumor with right lateral margin
4G. tumor with closest approach to the deep margin
4H-I additional sections of tumor, with left margin in 4H

5. The specimen container is labeled with the patient's identification and as "left tongue base ". It contains one piece of tissue, measuring

Status: complete

Page: 4 of 6

Patient Name: [REDACTED]

MRN: [REDACTED]

DOB: [REDACTED]

Gender: [REDACTED]

HCN: [REDACTED]

Ordering MD: [REDACTED]

Service: Otolaryngology

Visit #: [REDACTED]

Location: [REDACTED]

Facility: [REDACTED]

Copath #: [REDACTED]

Collected: [REDACTED]

Resulted: [REDACTED]

1.8 x 0.4 x 0.2 cm, which has previously been submitted in toto at time of frozen section.

5A frozen section, resubmitted

6. The specimen container labeled with the patient's identification and as "left neck level 1A and 1B" contains a single piece of fibroadipose tissue, measuring 4.4 x 4.0 x 2.9 cm. The submandibular gland is present, measuring 3.6 x 3.0 x 1.9 cm. Nine possible lymph nodes are identified, ranging in size from 0.2 cm in maximal dimension to 1.2 x 1.0 x 0.5 cm.

Representative sections:

6A submandibular gland
6B two possible lymph nodes
6C three possible lymph nodes
6D four possible lymph nodes

[page 6 of 7]
7. The specimen container is labeled with the patient's identification and as "left neck level 2A and 2B". It contains a single piece of fibroadipose tissue, measuring 3.7 x 3.2 x 1.5 cm. Two possible lymph nodes are identified, measuring 2.4 x 1.4 x 1.2 cm, and 1.5 x 0.6 x 0.5 cm.

Representative sections:

7A largest lymph node, bisected
7B second lymph node, bisected

8. The specimen container labeled with the patient's identification and as "left neck level 3" contains a piece of fibroadipose tissue, measuring 4.0 x 1.9 x 1.1 cm. 11 possible lymph nodes are identified, ranging in size from 0.2 x 0.2 x 0.2 cm to 1.4 x 0.9 x 0.5 cm.

8A four possible lymph nodes
8B four possible lymph nodes
8C two possible lymph nodes
8D one lymph node bisected

9. The specimen container labeled with the patient's identification and as left neck level 4 contains a single piece of fibroadipose tissue, measuring 2.8 x 1.2 x 0.9 cm. Seven possible lymph nodes are identified, ranging in size from 0.3 x 0.3 x 0.1 cm to 1.6 x 0.9 x 0.8 cm.

Representative sections:

9A 4 possible lymph nodes
9B 2 possible lymph nodes

Status: complete

Page: 5 of 6

Patient Name: [REDACTED]

MRN: [REDACTED]

DOB: [REDACTED]

Gender: [REDACTED]

HCN: [REDACTED]

Ordering MD: [REDACTED]

Service: Otolaryngology

Visit #: [REDACTED]

Location:

Facility:

Copath #: [REDACTED]

Collected: [REDACTED]

Resulted: [REDACTED]

9C largest lymph node, bisected

10. The specimen container labeled with the patient's identification and as "right perifacial node" contains a single lymph node, measuring 1.0 x 0.6 x 0.5 cm.

Submitted in toto in 10A

11. The specimen container is labeled with the patient's identification and as "surgical waste". It contains 3 pieces of skin, ranging in size from 5.0 x 1.0 x 0.2 cm to 10.6 x 3.5 x 0.3 cm. The skin is grossly

[page 7 of 7]
unremarkable. No sections are submitted.

QUICK SECTION

4. Posterior margin (black ink) of interest as per surgeon bisected into 4A, 4B:

-Margin uninvolved by carcinoma up to 0.3 cm.

5. Left tongue base, biopsy: negative for carcinoma.

Last slide received reported directly to

Status: complete

Page: 6 of 6

8/27/12

Source: NCI Genomic Data Commons file 410b942f-0a6e-4559-85a1-49a822fd1dcc (TCGA-CQ-A4CH.538065A2-31A1-446E-BF44-DC45DE7D261C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).